Gene-level copy-number profile of tumor specimen ALCH-B1VE-TTP1-A from ALCHEMIST case ALCH-B1VE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,076 days).
Specimen ALCH-B1VE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6928d66-2b0b-4130-87a5-1e5d3e512cda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/1c6e5324-ee08-44db-936b-8409d31403ad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 21,899; copy number 2: 34,123; copy number 3: 1,657; copy number 4: 141; copy number 5: 231; copy number 6: 203; copy number 7: 1; copy number 9: 114; copy number 10: 3; copy number 37: 1; copy number 72: 2.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,412,027–4,424,689, 1 gene: LINC01777.
- chr1:4,654,609–4,792,534, 2 genes: AJAP1, Z98886.1.
- chr1:13,254,212–13,275,627, 2 genes: PRAMEF5, PRAMEF32P.
- chr1:13,303,539–13,392,629, 6 genes: PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17.
- chr1:58,228,682–58,229,003, 1 gene (within-gene range 0–1): AL357373.1.
- chr8:40,900,016–40,901,854, 1 gene: AC048387.1.
- chr8:52,975,111–52,976,116, 1 gene: AC009800.1.
- chr14:95,662,480–95,662,598, 1 gene (within-gene range 0–1): AL133467.5.
- chr17:6,207,163–6,207,269, 1 gene: RNU6-1264P.
- chr17:45,731,703–45,734,669, 2 genes (within-gene range 0–1): AC217774.1, AC217774.2.
- chr17:45,844,881–45,847,067, 1 gene (within-gene range 0–1): SPPL2C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 555 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,389,468–27,390,145, 1 gene, copy number 5: FO393419.1.
- chr1:143,736,066–155,660,245, 540 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr5:10,225,507–10,269,918, 5 genes, copy number 5: ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3.
- chr16:32,439,069–32,441,159, 1 gene, copy number 6: PABPC1P13.
- chr21:43,414,483–43,479,534, 4 genes, copy number 9–37: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 7–10 (within-gene range 1–72): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 72: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 19,650. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
